CCDI case PBBVGX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/84ef2ff8-6652-43ee-b553-e293415faff2

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Sarcoma, NOS: ICD-O-3 morphology code: 8800/3; Tissue or organ of origin: Ovary; Age at diagnosis: 14.7 years (5,366 days).

Biospecimens (3 samples)
- Sample 0DIMVN: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIMWI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIMWX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
